Surgical pathology report (de-identified scan), TCGA case TCGA-24-2019, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2019-01A (Primary Tumor).

[page 1 of 6]
TCGA-24-2019

DIAGNOSIS:

OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY(INCLUDING FS1)
- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- ADENOCARCINOMA INVOLVES THE OVARIAN SURFACE
- SEE COMMENT AND SYNOPSIS

FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA IN PERITUBAL SOFT TISSUE
- ENDOMETRIOSIS
- FOCAL TUBAL INTRAEPITHELIAL NEOPLASIA

OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- ADENOCARCINOMA INVOLVES THE OVARIAN SURFACE

FALLOPIAN TUBE, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA IN PERITUBAL SOFT TISSUE
- ENDOMETRIOSIS
- FOCAL TUBAL INTRAEPITHELIAL NEOPLASIA

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY
- CHRONIC INFLAMMATION WITH FOLLICULAR CERVICITIS

UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- LATE SECRETORY PATTERN

UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- ADENOMYOSIS

UTERUS, SEROSAL SURFACE, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, ANTERIOR CUL-DE-SAC, EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, LABELED "LEFT PELVIC LYMPH NODE," EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- SEE COMMENT

[page 2 of 6]
[REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED]

SOFT TISSUE, SIGMOID COLON TUMOR, EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, LABELED "ANTERIOR ABDOMINAL WALL NODULE," EXCISION
- METASTATIC ADENOCARCINOMA IN TWO OF TWO LYMPH NODES (2/2)

SOFT TISSUE, RECTAL NODULE, EXCISION (FS2)
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, OMENTUM, OMENTECTOMY
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- NO EVIDENCE OF MALIGNANCY IN ONE INCIDENTAL LYMPH NODE

SOFT TISSUE, LABELED "RIGHT DIAPHRAGM TUMOR," EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SOFT TISSUE, ILEAL NODULE, EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SMALL INTESTINE, TERMINAL ILEUM, ILEOCOLECTOMY
- SEROSAL IMPLANTS OF METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- SEROSAL ADHESIONS

LARGE INTESTINE, CECUM, ILEOCOLECTOMY
- SEROSAL IMPLANTS OF METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA
- SEROSAL ENDOMETRIOSIS WITH ASSOCIATED DENSE FIBROSIS AND ADHESIONS

LYMPH NODES, MESENTERIC, EXCISION
- METASTATIC ADENOCARCINOMA IN ONE OF FIVE LYMPH NODES (1/5)

SOFT TISSUE, RIGHT PELVIC NODULE, EXCISION
- METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA

SKIN AND SOFT TISSUE, UMBILICUS, EXCISION
- NO EVIDENCE OF MALIGNANCY

[REDACTED]

By this signature, I attest that the above diagnosis is based upon my personal examination of the slides (and/or other material indicated in the diagnosis).

[REDACTED]

***Report Electronically Reviewed and Signed Out By [REDACTED]

[REDACTED]

Intraoperative Consultation:

An intraoperative non-microscopic consultation was obtained and interpreted as: "Brought to frozen is a 'right tube and ovary,' consisting of an 80 gram, 9.5 x 3 x 8.2 cm multicystic and solid mass. Numerous excrescences are present on the surface of the ovary. Sectioned to show a complex, multicystic mass without identifiable residual normal ovarian parenchyma. Portion frozen as 'FS1.' Rest for permanents," by [REDACTED]

"Called to pick up 'left tube and ovary,' consisting of a 60 gram ovary reportedly in formalin for a few minutes. A tan-brown, heterogeneous tumor is sampled for [REDACTED]. Rest for permanents," [REDACTED]

FS1: Ovary, right, biopsy
- "Poorly differentiated adenocarcinoma, favor Mullerian," by [REDACTED]

[REDACTED]

FS2: Soft tissue, rectal nodule, biopsy

[page 3 of 6]
[REDACTED]

Microscopic Description and Comment:

Histologic evaluation of the ovarian mass shows poorly differentiated serous adenocarcinoma. While the majority of the tumor shows typical serous features, focal areas have cytologic features reminiscent of neuroendocrine differentiation including nuclear molding and a lack of prominent nucleoli; these areas also show immunoreactivity for the neuroendocrine markers chromogranin and synaptophysin (immunoreactivity with pan-cytokeratin is also noted). Focal expression of neuroendocrine markers in serous adenocarcinoma has been described in the literature, however, no large studies have evaluated the impact of this finding on patient outcome. Clinical correlation is therefore required.

Examination of the specimen labeled "left pelvic lymph node," which was entirely submitted for histologic examination, shows metastatic poorly differentiated serous adenocarcinoma. Fragments of lymphoid tissue are present, but there is no definitive lymph node architecture. The findings could represent a lymph node that has been effaced by metastatic disease, or a soft tissue tumor deposit of adenocarcinoma with a lymphocytic response. Clinical correlation is required.

[REDACTED]

[REDACTED]

History:

The patient is a [REDACTED] with an ovarian mass. Operative procedure: Exploratory laparotomy, total abdominal hysterectomy, bilateral salpingo-oophorectomy and tumor debulking.

Specimen(s) Received:

A: RIGHT OVARY AND TUBE
B: ANTERIOR CULDESAC
C: LEFT PELVIC LYMPH NODE
D: LEFT OVARY AND TUBE
E: UTERUS AND CERVIX
F: SIGMOID COLON TUMOR
G: ANTERIOR ABDOMINAL WALL NODULE
H: RECTAL NODULE
I: OMENTUM
J: RIGHT DIAPHRAGM
K: ILEO NODULE
L: ILEUM AND CECUM
M: RIGHT PELVIC NODULE
N: UMBILICUS

Gross Description:

The specimens are received in fourteen formalin-filled containers each labeled [REDACTED]. The first container is labeled "right tube and ovary/ FS1/X." It holds a white tissue cassette labeled "FS1" that contains a frozen section remnant measuring 2 x 1.5 x 0.2 cm. Labeled A1 (FS1). Also in the container is a previously sectioned, 9.5 x 3 x 8.2 cm ovary. The serosal surface is studded with multiple, tan-white, papillary excrescences. The ovary has been sectioned to show a multicystic mass with no grossly identifiable normal ovarian parenchyma. On cut surface, the mass has papillary features and is solid in many areas. Along one surface is a 4.5 x 0.5 cm portion of fallopian tube. Paratubal adhesions with tumor are noted at the fimbriated end. Labeled A2 to A5 - additional sections of mass; A6 - fallopian tube with paratubal adhesions. [REDACTED]

The second container is labeled "anterior cul de sac." It holds multiple tan tissue fragments, measuring 2.5 x 2 x 0.2 cm in aggregate. Many of the fragments have a slightly papillary architecture, consistent with involvement by metastatic disease. [REDACTED]

The third container is labeled "left pelvic lymph node." It holds a tan-brown tissue fragment, measuring 2 x 2 x 0.2 cm. No definitive lymphoid tissue is identified. [REDACTED]

[page 4 of 6]
[REDACTED]

The fourth container is labeled "left tube and ovary." It holds a 67 gram specimen measuring 8 x 8 x up to 5 cm. The majority of the ovarian surface is involved by a tan papillary tumor. The ovary is sectioned to show extensive tumor involvement. Multiple hemorrhagic cysts are also present. Along one surface is a 3.5 x 0.5 cm portion of fallopian tube with no definitive serosal nodules. Labeled D1 - intraparenchymal and serosal involvement by tumor; D2, D3 - additional sections of tumor; D4 - fallopian tube. [REDACTED]

The fifth container is labeled "uterus and cervix." It holds a 140 gram uterus measuring 9 cm in length, 8 cm cornu to cornu, and 4 cm anterior to posterior. The bilateral adnexa are absent. The 3 x 3.5 cm tan ectocervix has multiple pinpoint areas of mucosal dark red congestion. The serosal surface has multiple serosal densities (0.1 to 0.2 cm), present primarily over the posterior aspect. The 2.8 cm long endocervical canal is lined by unremarkable mucosa. Scattered Nabothian cysts are present. The 4 x 2.2 cm endometrial cavity is unremarkable. The endometrium measures 0.2 cm thick with a myometrial thickness of 1.5 cm. Labeled E1 - anterior ectocervix; E2 - posterior ectocervix; E3 - anterior endomyometrium; E4 - posterior endomyometrium; E5 - posterior serosal nodules. [REDACTED]

The sixth container is labeled "sigmoid colon tumor." It holds multiple pieces of fibroadipose tissue measuring 2 x 1 x 0.3 cm in aggregate. Many of the tissue fragments are consistent with involvement by metastatic disease. Filtered and wrapped. [REDACTED]

The seventh container is labeled "anterior abdominal wall nodule." It holds two pieces of fibroadipose tissue measuring 1.5 x 1 x 0.3 cm and 1 x 0.5 x 0.2 cm. Both pieces have firm white densities, consistent with involvement by metastatic disease. [REDACTED]

The eighth container is labeled "rectal nodule/FS2." It holds a frozen section remnant measuring 1 x 0.3 x 0.2 cm. Labeled H1 (FS2). [REDACTED]

The ninth container is labeled "omentum." It holds a piece of fibroadipose tissue measuring 20 x 10 x 3 cm. The specimen is studded with innumerable white firm nodules, the largest measuring 4.5 cm in greatest dimension. [REDACTED]

The tenth container is labeled "right diaphragm tumor." It holds tan, clear, thin tissue fragment measuring 0.5 x 0.5 x 0.1 cm. Filtered. Wrapped. [REDACTED]

The eleventh container is labeled "ileal nodule." It holds multiple tan-brown tissue fragments, measuring 0.7 x 0.5 x 0.2 cm, in aggregate. Filtered. Wrapped. [REDACTED]

The twelfth container is labeled "ileum and cecum." It holds an ileocectomy specimen consisting of terminal ileum (8.5 x 2 cm) and cecum (10 x 3 cm). The serosal surface and the mesenteric fat of both the terminal ileum and cecum are involved by tan friable tumor nodules that range from 0.1 cm to 3 cm in maximal dimension. The periceal soft tissue is sectioned to show multiple lymph nodes. No appendix is identified. Labeled L1 - terminal ileum margin; L2 - terminal ileal serosal nodule; L3 - cecal margin; L4 - additional section of cecum with serosal irregularity; L5 - periceal mass; L6 - lymph nodes. [REDACTED]

The thirteenth container is labeled "right pelvic nodule." It holds a slightly firm tan piece of fibrous tissue, measuring 1 x 0.5 x 0.2 cm. Wrapped. [REDACTED]

The fourteenth container is labeled "umbilicus." It holds a umbilicus specimen with a 4 x 1.5 cm tan, hairbearing skin ellipse with a central umbilicus measuring 1.5 x 0.1 cm. The subcutaneous tissue is tan-yellow and measures a depth of 3 cm. No definitive lesions or masses are noted. [REDACTED]

[REDACTED]

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

HISTOPATHOLOGIC TYPE

The histologic diagnosis is serous adenocarcinoma

TUMOR LOCATION

[page 5 of 6]
SURGICAL PATHOLOGY REPORT

The locations of the primary tumor(s) are the right and left ovary (synchronous primary tumors)

HISTOLOGIC GRADE

The histologic grade is poorly differentiated (G3)

TUMOR INVASION

Tumor is identified on the ovarian surface(s)

Tumor does invade the adjacent fallopian tube/peritubal soft tissue

TUMOR INVOLVEMENT

Tumor involvement of the pelvic peritoneum/soft tissue is present

Metastatic involvement of the extrapelvic peritoneum is present

Metastatic involvement of the omentum is present

TUMOR SIZE

The maximum dimension of tumor implants outside the true pelvis is greater than or equal to 2 cm

PRIMARY TUMOR (T)

Based on the above information, the primary tumor is classified as macroscopic peritoneal metastasis beyond pelvis more than 2 cm in greatest dimension or regional lymph node metastasis (T3c/IIIC)

REGIONAL LYMPH NODES (N)

The regional lymph nodes are classified as regional lymph node metastasis (N1)

The total number of regional lymph nodes examined is 8

The total number of metastatically-involved lymph nodes is 3

DISTANT METASTASIS (M)

The status of distant tumor site cannot be assessed (MX)

STAGE GROUPING

The Final AJCC/UICC/FIGO stage is T3c/N1/MX (Stage X)

The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

Source: NCI Genomic Data Commons file 2142a559-7d2d-42f4-835d-68b79eb29122 (TCGA-24-2019.15A77E5D-ACFB-4013-81DE-EF9D2F6398D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).